Gene-level copy-number profile of tumor specimen TCGA-DD-AAVQ-01A from TCGA case TCGA-DD-AAVQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 38.1 years (13,911 days).
Specimen TCGA-DD-AAVQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.8448d778-5823-4b0f-a07f-4d0495480e6c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AAVQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 400 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a06549ce-3e6d-44c0-b513-417498b94e54

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,742; copy number 1: 19,651; copy number 2: 33,692; copy number 3: 1,307; copy number 4: 2,785; copy number 5: 6; copy number 6: 19; copy number 7: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AAVQ-01A-11D-A40Q-01): tumor purity 0.35, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 374 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:164,597,719–190,092,279, 365 genes (broad region; genes not listed).
- chr6:30,451,139–30,494,194, 5 genes: AL662873.1, TMPOP1, SUCLA2P1, RANP1, HLA-E.
- chr12:33,982,465–34,058,745, 4 genes: Y_RNA, AC046130.1, ALG10, AC046130.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 46 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 7 (within-gene range 2–7): AC244205.1.
- chr2:88,857,161–89,046,466, 20 genes, copy number 7: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13.
- chr4:49,203,171–49,589,529, 19 genes, copy number 6: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr10:30,529,517–30,629,762, 6 genes, copy number 5: AL590068.4, AL590068.1, RN7SL63P, AL590068.2, AL590068.3, LYZL2.

Autosomal genes at a single copy (total copy number 1): 19,600. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
